Surgical pathology report (de-identified scan), TCGA case TCGA-B5-A0KB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Duke, specimen TCGA-B5-A0KB-01B (Primary Tumor).

[page 1 of 2]
ICD-0-3
Adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1 3/25/11 *hr*

Surg Path

CLINICAL HISTORY:

Malignant neoplasm corpus uteri.

GROSS EXAMINATION:

A. "Uterus, bilateral tubes and ovaries", received fresh and placed in formalin on at pm is a markedly disrupted fragmented uterus with attached bilateral adnexa, 235 grams overall. The cervix is received in several fragments as well as several additional separate nodules consistent with leiomyomata. The uterine corpus is 9.5 x 9.5 x 8.2 cm overall. The endometrial cavity is remarkable for a tan, fungating, friable tumor mass which is approximately 3.5 x 2.5 x 1.5 cm. Due to the fragmented appearance of the uterus, anterior and posterior endometrial walls cannot be ascertained. Sectioning through the tumor mass reveals a tan-gray-white cut surface. The tumor mass is approximately 1.1 cm thick at its thickest surface. The tumor mass is approximately 1.1 cm thick at its thickest myometrial of up to 2.6 cm. The myometrium is tan, trabeculated, and is remarkable for numerous leiomyomata, the largest of which is 6.5 cm in greatest dimension. The cut surfaces of the leiomyomata are white, whorled, no hemorrhage or necrosis is grossly noted. Additionally received in the same container are two fragments of tissue compatible with disrupted cervix, the cervix is 3.5 x 2.5 cm overall, the endocervical canal is unremarkable. Also received are several well-circumscribed leiomyomata, the largest of which is 4 cm in greatest dimension. The cut surfaces are white, whorled, and no hemorrhage or necrosis is noted. The presumed left ovary is 2.7 x 1.5 x 0.9 cm. The external surface is tan-yellow and corrugated. The associated fallopian tube segment is 4.5 cm long x 0.4 cm in diameter. One end is blunted, the opposing end contains tan-pink fimbria. Sectioning of the ovary discloses a tan-yellow, 1.1 cm cyst. The remaining ovarian parenchyma is unremarkable. The presumed right ovary is tan-yellow, 1.5 x 1.3 x 1 cm and displays a cerebriform external surface. The associated fallopian tube segment is 3.5 cm long x 0.4 cm in diameter. One end is blunted, the opposing end contains tan-pink, delicate fimbria. The cut surface of the ovary discloses a tan-yellow, homogeneous cut surface, with several focal thin-walled cysts, the largest of which is 0.2 cm in greatest dimension.

BLOCK SUMMARY:

- A1-2- full-thickness endometrial tumor and underlying myometrium, bisected
- A3-6- full-thickness tumor/endomyometrium
- A7- cervix
- A8-10- representative sections of leiomyomata
- A11- presumed left ovary and fallopian tube
- A12- presumed right ovary and fallopian tube
- A13- normal appearing endometrium
- A14-15- additional sections of cervix
- A16- lower uterine segment
- A17-18- additional sections of fallopian tube

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Total hysterectomy with bilateral salpingo-oophorectomy

PATHOLOGIC STAGE (AJCC 7th Edition): pT1b pNx pMX

NOTE: Information on pathology stage and the operative procedure is

[page 2 of 2]
transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. UTERUS, BILATERAL TUBES AND OVARIES (TOTAL ABDOMINAL HYSTERECTOMY WITH SALPINGO-OOPHORECTOMY):

UTERUS: 235 GRAMS

CARCINOMA OF THE ENDOMETRIUM:

TUMOR SITE: CORPUS.

HISTOLOGIC TYPE: ENDOMETRIOID ADENOCARCINOMA.

FIGO GRADE: 3.

TUMOR SIZE: 3.5 X 2.5 X 1.5 CM.

MAXIMUM DEPTH OF MYOMETRIAL INVASION: 1.8 CM, IN A 2.5 CM THICK WALL.

LYMPHATIC/VASCULAR INVASION: PRESENT.

NON-NEOPLASTIC ENDOMETRIUM: NOT HYPERPLASTIC.

REMAINING MYOMETRIUM: ADENOMYOSIS, MULTIPLE LEIOMYOMATA UP TO 4 CM.

CERVIX: UNINVOLVED.

SEROSA: FREE OF TUMOR.

SPECIMEN MARGINS: NOT INVOLVED.

LEFT OVARY: NEGATIVE FOR TUMOR

RIGHT OVARY: NEGATIVE FOR TUMOR

FALLOPIAN TUBE, RIGHT AND LEFT: NEGATIVE FOR TUMOR.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

Performed by:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f3ee307d-ce23-45f9-a475-c8d60dc08584 (TCGA-B5-A0KB.2C744545-8FF8-4A07-A8F2-A47D28B2A8E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).